TCGA case TCGA-SI-A71P — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Peripheral nerves and autonomic nervous system; Tissue source site: Washington University St. Louis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2560fb5b-5f49-4d38-8f61-1ab911aed3eb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; ICD-10 code: C47.1; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of upper limb and shoulder; Site of resection or biopsy: Peripheral nerves and autonomic nervous system of upper limb and shoulder; Classification of tumor: primary; Age at diagnosis: 50.3 years (18,367 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 13.5.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 6.
- Days to follow up: 603 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 771 days (2.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 441.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SI-A71P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-SI-A71P-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SI-A71P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SI-A71P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Site of primary tumor other: Spinal Cord Nreve Roots; Tumor total necrosis: Extensive Necrosis (>50%); Disease multifocal indicator: Yes; Discontinuous lesions count: 6; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Synovial sarcoma: Mpnst nf indicator: NF1; Mpnst nf familial or sporadic: Familial; Mpnst plexiform neurofibroma site: Yes; Mpnst nf1 genetic testing indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 174; Days from index date to pharmaceutical treatment ended: 269; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment: Days from index date to radiation therapy started: 113; Days from index date to radiation therapy ended: 128; Radiation therapy type: External; Radiation total dose: 21.6; Radiation adjuvant fractions total: 12; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 771 days; disease-specific survival: no event (censored), 771 days; progression-free interval: no event (censored), 771 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SI-A71P-01A-12D-A33D-01): tumor purity 0.32, ploidy 3.26, whole-genome doublings 1.
